Somatic mutation profile of tumor specimen ALCH-B4FP-TTP1-A (aliquot ALCH-B4FP-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4FP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,968 days).
Specimen ALCH-B4FP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3de1eef-9e49-4f33-bc9b-c89df2751ec0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4FP-NB2-A (Blood Derived Normal), aliquot ALCH-B4FP-NB2-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ec4ee5-22b1-4b16-adcc-d48630ef5389

The open-access MAF lists 54 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Intron 6, 5'Flank 2, Splice Site 1, 3'Flank 1, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 151/485 reads (31%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 87/327 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATL1 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1265964061, COSV63295952; called by muse, mutect2, varscan2
- CGNL1 | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1239864782; called by muse, mutect2
- FLI1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.254); catalogued as rs1408952807; called by muse, mutect2
- GOLGA6L10 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 43/1256 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1331426872; called by muse, mutect2
- NRXN3 | c.1427G>A p.R476H (on ENST00000335750 / NM_001330195.2; = p.R103H on NM_004796.6) | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199543320, COSV59730608; called by muse, mutect2, varscan2
- PAX5 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63908541; called by muse, mutect2
- PPP1R3B | c.365T>C p.L122S | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs761632564; called by muse, mutect2
- SORT1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs896558074; called by muse, mutect2
- TFEB | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1394029477; called by muse, mutect2, varscan2
- ZNF716 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs781983140, COSV101348622; called by muse, mutect2, varscan2
- ACSM2A | c.114G>C p.Q38H | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- ATP13A5 | c.936_941delinsACCTGT p.M312_T314delinsIPV | Missense Mutation (ONP) | VAF 12/71 reads (17%) | called by mutect2*, pindel
- CAD | c.6481-1G>A p.X2161_splice | Splice Site (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- CLEC2L | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2
- ERICH4 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ERP44 | c.983A>G p.H328R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- FAM149A | c.1756T>G p.S586A (on ENST00000356371 / NM_001367768.2; = p.S295A on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2
- JSRP1 | c.777G>C p.E259D | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MAGEA11 | c.676A>T p.I226L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MBOAT2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- MTHFD2 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- MYH2 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR11H12 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- PAPSS2 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- PHLPP1 | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.551); called by muse, varscan2
- PRAMEF19 | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SEC22B | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TPTE | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM23 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRPV1 | c.1424T>G p.V475G | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2
- UBXN1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, varscan2
- VN1R5 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- WASHC5 | c.1496_1503del p.V499Dfs*38 | Frame Shift Del (DEL) | VAF 74/584 reads (13%) | called by mutect2, pindel
- ABCA13 | c.423A>G p.E141= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs1435195294; called by muse, mutect2
- ADGRG4 | c.6324C>A p.S2108= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs755307036; called by muse, mutect2
- DDX60L | c.3273G>A p.V1091= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- GPR179 | c.3519C>T p.G1173= (on ENST00000621958; = p.G1172= on NM_001004334.4) | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- NALCN | c.3036C>T p.S1012= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs760941305, COSV99218122; called by muse, mutect2
- NRXN3 | c.1689G>A p.T563= (on ENST00000335750 / NM_001330195.2; = p.T190= on NM_004796.6) | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs768400919, COSV59811028; called by muse, varscan2
- OR5AU1 | c.901T>C p.L301= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- PHF21B | c.1470G>A p.Q490= | Silent (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.2202C>T p.T734= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- DISC1 | c.1117+20531T>C | Intron (SNP) | VAF 26/526 reads (5%) | called by muse, mutect2
- DUSP15 | c.13-13G>C | Intron (SNP) | VAF 35/205 reads (17%) | catalogued as rs1423694016; called by muse, mutect2, varscan2
- HSD17B7P2 | n.69C>T | RNA (SNP) | VAF 15/265 reads (6%) | called by muse, mutect2
- ITGA9 | c.2541+43C>A | Intron (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156675 C>A | 3'Flank (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- PNLIPRP1 | c.331-368A>C | Intron (SNP) | VAF 10/213 reads (5%) | called by muse, mutect2
- PTPN9 | c.528+3953A>G | Intron (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134175628 G>A | 5'Flank (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.1865+456T>A | Intron (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- USP2 | chr11:119381895 G>T | 5'Flank (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
